Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A4K7, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A4K7-01A (Primary Tumor).

Sex: M

Collected:

Accession:

Received:

Case type: Surgical Case

DIAGNOSIS

(A) TOTAL THYROIDECTOMY PAPILLARY THYROID CARCINOMA, CONVENTIONAL TYPE

Location: Left lobe
Multi-focal: No
Size = 2.5 cm
Extrathyroidal extension: Present, extending into skeletal muscle
Lymphovascular invasion: Present
Resection Margins: Tumor abutting the margin
Background Thyroid: Chronic lymphocytic thyroiditis
Lymph nodes:

METASTATIC PAPILLARY THYROID CARCINOMA IN 1 LYMPH NODE

Location: Periglandular

Extracapsular extension: Absent

1CD-0-3

carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS c73.9

hw
10/4/12

(B) PORTION OF LEFT SUPERIOR PARATHYROID:

Fragments of parathyroid

GROSS DESCRIPTION

(A) TOTAL THYROIDECTOMY - A total thyroidectomy specimen consists of right lobe (4.3 x 2.2 x 1.4 cm), left lobe (4.9 x 3.2 x 3.5 cm) and isthmus (1 x 1.2 x 0.5 cm). Cut surface reveals unremarkable right lobe and isthmus. A well-circumscribed lobular and granular tumor (2.5 x 2.5 x 1.8 cm) is identified in the upper and middle portion of left lobe. The tumor grossly extends to anterior, posterior and lateral capsule.

INK CODE: Tumor surface - black.

SECTION CODE: A1, isthmus; A2, A3, representative section of right lobe; A4-A10, tumor and uninvolved thyroid tissue of left lobe from superior to inferior.

(B) PORTION OF LEFT SUPERIOR PARATHYROID - Two small fragments of tiny soft tissue (less than 0.1 x less than 0.1 x less than 0.1 cm each). Entirely submitted in B, for frozen evaluation.

*FS/DX: PARATHYROID GLAND.

CLINICAL HISTORY

Papillary thyroid carcinoma

SNOMED CODES

T-B6000, T-7000, T-C4200, M-80503, M-B0630, M-80506

"Some tests reported here may have been developed and performance characteristics determined by These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Entire report and diagnosis completed by:

Surgical Pathology Report

File under: Pathology

ICDPA Discrepancy		

Source: NCI Genomic Data Commons file 2de9b9af-6893-4af7-b097-8ec0ea4dae29 (TCGA-EL-A4K7.74E7A957-CB8F-4D15-9EA7-40E1B7EC36FA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).